Gene-level copy-number profile of tumor specimen TCGA-2G-AAFD-01A from TCGA case TCGA-2G-AAFD, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 31.1 years (11,360 days).
Specimen TCGA-2G-AAFD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d70cf047-7455-4202-b9f3-ec3a523e3c02.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAFD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/f0f2de3d-b940-4688-aaad-b9f8607d1f0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 555; copy number 2: 20,328; copy number 3: 25,582; copy number 4: 10,523; copy number 5: 941; copy number 6: 10; copy number 9: 110; copy number 10: 82; copy number 11: 353; copy number 12: 32; copy number 14: 9; copy number 15: 61; copy number 16: 20; copy number 22: 4; copy number 23: 32; copy number 24: 10; copy number 25: 47; copy number 26: 78; copy number 27: 5; copy number 28: 65; copy number 29: 34.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr9:41,890,314–42,668,887, 20 genes: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4.
- chr9:64,369,394–64,440,180, 3 genes: ANKRD20A4P, RNU6-1193P, SNX18P9.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 942 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–60,796,103, 139 genes, copy number 11–22 (broad region; genes not listed).
- chr12:273,954–32,993,754, 803 genes, copy number 9–29 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
